Somatic mutation profile of tumor specimen TCGA-29-1702-01A (aliquot TCGA-29-1702-01A-01W-0633-09) from TCGA case TCGA-29-1702, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 84.6 years (30,910 days).
Specimen TCGA-29-1702-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 24cde5c1-1666-46db-aa4f-a94a67f15ff1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-29-1702-10A (Blood Derived Normal), aliquot TCGA-29-1702-10A-01W-0633-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d377b61-f19e-40ab-8342-055e765b8c8e

The open-access MAF lists 53 somatic variants for this specimen: 38 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 30, Silent 15, Frame Shift Del 4, Nonsense Mutation 2, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 469/472 reads (99%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAM29 | c.2407C>A p.Q803K | Missense Mutation (SNP) | VAF 130/569 reads (23%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.01); catalogued as COSV63662395, COSV63665952; called by muse, varscan2
- AGAP6 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 164/355 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.292); catalogued as COSV65018086; called by muse, mutect2, varscan2
- AMOTL1 | c.253G>T p.V85L | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.503); catalogued as COSV54417340; called by muse, mutect2, varscan2
- AOC3 | c.985C>T p.R329* | Nonsense Mutation (SNP) | VAF 42/140 reads (30%) | catalogued as rs766271081, COSV53827949; called by muse, mutect2, varscan2
- B4GAT1 | c.988G>A p.V330M | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs751991894, COSV60820432; called by muse, mutect2, varscan2
- CDC20 | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs750186760, COSV60521849; called by muse, mutect2, varscan2
- EMB | c.391A>G p.I131V | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0.096); catalogued as rs138980748; called by muse, mutect2, varscan2
- FGD1 | c.2221_2240del p.E741Qfs*27 | Frame Shift Del (DEL) | VAF 16/69 reads (23%) | catalogued as COSV64309244; called by mutect2, pindel, varscan2
- GNAI3 | c.492G>T p.Q164H | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV63983366, COSV63984218; called by muse, mutect2, varscan2
- HAUS2 | c.495A>T p.K165N | Missense Mutation (SNP) | VAF 37/209 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53000719; called by muse, mutect2, varscan2
- HIRA | c.2606A>T p.D869V | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54277570; called by muse, mutect2, varscan2
- HTR1A | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1222021133, COSV60500236; called by muse, mutect2, varscan2
- IL12RB2 | c.1064G>A p.G355E | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52026050; called by muse, mutect2, varscan2
- KIF21B | c.2872C>G p.R958G | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.041); catalogued as COSV100145201, COSV59759993; called by muse, varscan2
- KIT | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 40/63 reads (63%) | SIFT tolerated (0.11); PolyPhen benign (0.132); catalogued as rs376469897, COSV55391289, COSV55422608; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NELFCD | c.1009A>G p.I337V (on ENST00000602795; = p.I319V on NM_198976.4) | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs534907805, COSV53884256; called by muse, mutect2, varscan2
- OPN1LW | c.852C>A p.Y284* | Nonsense Mutation (SNP) | VAF 75/220 reads (34%) | catalogued as COSV64049496; called by muse, mutect2, varscan2
- P2RY1 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.692); catalogued as rs1406416376, COSV59309293; called by muse, mutect2, varscan2
- PCDHA4 | c.731G>A p.R244K | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.007); catalogued as COSV63544186; called by muse, mutect2, varscan2
- PFAS | c.2950G>T p.A984S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.012); catalogued as COSV58982057; called by muse, mutect2, varscan2
- PFDN5 | c.284C>G p.T95R | Missense Mutation (SNP) | VAF 153/367 reads (42%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.526); catalogued as COSV54476603; called by muse, mutect2, varscan2
- PLG | c.984C>A p.D328E | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV51980360, COSV51984788; called by muse, mutect2, varscan2
- PRKCB | c.199T>A p.C67S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as COSV57791445; called by muse, mutect2, varscan2
- RALGAPB | c.2432_2433del p.C811Yfs*8 | Frame Shift Del (DEL) | VAF 36/143 reads (25%) | catalogued as COSV53441433; called by mutect2, pindel, varscan2
- RNF111 | c.2869C>T p.R957C (on ENST00000557998 / NM_001270530.1; = p.R949C on NM_017610.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/200 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs780099637, COSV62088347; called by muse, mutect2, varscan2
- RPGRIP1 | c.1885G>C p.E629Q | Missense Mutation (SNP) | VAF 66/264 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52845306, COSV52845587; called by muse, mutect2, varscan2
- SH3GL3 | c.266C>T p.T89M | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs201410848, COSV61054371; called by muse, mutect2, varscan2
- SH3RF3 | c.2120G>A p.C707Y | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV58691137; called by muse, mutect2, varscan2
- SRP72 | c.1561C>A p.L521I | Missense Mutation (SNP) | VAF 66/290 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV61378558; called by muse, mutect2, varscan2
- SRSF7 | c.111A>C p.L37F | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57447864; called by muse, mutect2, varscan2
- TARBP1 | c.2734A>T p.S912C | Missense Mutation (SNP) | VAF 41/206 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.338); catalogued as COSV50194721; called by muse, mutect2, varscan2
- TMPRSS11F | c.514+2T>G p.X172_splice | Splice Site (SNP) | VAF 40/87 reads (46%) | catalogued as COSV62468039, COSV62468276; called by muse, mutect2, varscan2
- VCPIP1 | c.642C>A p.D214E | Missense Mutation (SNP) | VAF 42/696 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.473); catalogued as COSV100125806; called by muse, mutect2
- ZNF439 | c.170C>G p.S57C | Missense Mutation (SNP) | VAF 66/311 reads (21%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.995); catalogued as COSV58310322; called by muse, mutect2, varscan2
- CASP6 | c.447_448del p.H149Qfs*31 | Frame Shift Del (DEL) | VAF 18/75 reads (24%) | called by pindel, varscan2
- RAB3IP | c.1129_1139del p.Q377Vfs*8 (on ENST00000550536 / NM_175623.4; = p.Q361Vfs*8 on NM_022456.5) | Frame Shift Del (DEL) | VAF 13/133 reads (10%) | called by mutect2, pindel
- TMEM268 | c.472_474del p.K158del | In Frame Del (DEL) | VAF 14/47 reads (30%) | called by pindel, varscan2
- ABCA13 | c.12129C>T p.R4043= | Silent (SNP) | VAF 78/177 reads (44%) | catalogued as rs751562649, COSV71290250; called by muse, mutect2, varscan2
- ARHGEF15 | c.207C>T p.S69= | Silent (SNP) | VAF 32/161 reads (20%) | catalogued as COSV62725334; called by muse, mutect2, varscan2
- ASXL1 | c.555A>G p.E185= | Silent (SNP) | VAF 34/69 reads (49%) | catalogued as COSV60114977; called by muse, mutect2, varscan2
- DCAF4L2 | c.111C>T p.L37= | Silent (SNP) | VAF 69/74 reads (93%) | catalogued as COSV60478586; called by muse, mutect2, varscan2
- DPM3 | c.225G>A p.Q75= (on ENST00000341298; = p.Q105= on NM_018973.3) | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as COSV57597502; called by muse, mutect2, varscan2
- FAM149A | c.1959G>A p.T653= (on ENST00000356371 / NM_001367768.2; = p.T362= on NM_015398.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as rs1210804020, COSV57029159; called by muse, mutect2, varscan2
- MVK | c.147G>A p.V49= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as rs762533833, COSV57170791; called by muse, mutect2, varscan2
- NUF2 | c.1000T>C p.L334= | Silent (SNP) | VAF 47/258 reads (18%) | catalogued as COSV54845311; called by muse, mutect2, varscan2
- SHANK2 | c.3840C>T p.N1280= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV53610297; called by muse, mutect2, varscan2
- TMEM71 | c.144C>T p.C48= | Silent (SNP) | VAF 70/300 reads (23%) | catalogued as rs778255235, COSV63456965; called by muse, mutect2, varscan2
- TRPV3 | c.1554G>A p.S518= | Silent (SNP) | VAF 79/79 reads (100%) | catalogued as rs755434696, COSV100028211, COSV56793379; called by muse, mutect2, varscan2
- UNG | c.414C>G p.T138= (on ENST00000242576 / NM_080911.3; = p.T129= on NM_003362.4) | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV54358091; called by muse, varscan2
- VNN2 | c.897T>C p.L299= | Silent (SNP) | VAF 80/402 reads (20%) | catalogued as COSV58473410; called by muse, mutect2, varscan2
- ZEB1 | c.2316C>T p.C772= | Silent (SNP) | VAF 62/390 reads (16%) | catalogued as rs143340752, COSV100314537; called by mutect2, varscan2
- ZNF479 | c.303G>A p.Q101= | Silent (SNP) | VAF 56/221 reads (25%) | catalogued as COSV58641355; called by muse, mutect2, varscan2
